Somatic mutation profile of tumor specimen TCGA-AA-A00N-01A (aliquot TCGA-AA-A00N-01A-02W-A00E-09) from TCGA case TCGA-AA-A00N, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.7 years (27,667 days).
Specimen TCGA-AA-A00N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f954b9a-2f8b-4a0b-9f68-8d4aec10977b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A00N-10A (Blood Derived Normal), aliquot TCGA-AA-A00N-10A-01D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d311e6f-0820-4290-b461-8491edbf3bb0

The open-access MAF lists 5,092 somatic variants for this specimen: 3,929 protein-altering or splice-affecting, 950 silent, 213 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,403, Silent 950, Nonsense Mutation 423, Intron 95, RNA 48, Splice Region 47, Splice Site 38, 3'UTR 36, 5'UTR 25, Frame Shift Ins 11, 3'Flank 7, Nonstop Mutation 3.

Variants (750 of 5,092; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH3A2 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72547562, CM993307, CM993308; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- APC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 37/188 reads (20%) | hotspot (GDC flag); catalogued as CM106374, COSV57326063, COSV57397024; called by muse, mutect2, varscan2
- ATM | c.5188C>T p.R1730* | Nonsense Mutation (SNP) | VAF 34/171 reads (20%) | catalogued as rs764389018, CM990211, COSV53730827; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780290, CM970224, COSV55522473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779823379, CM120107, COSV67502170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD3 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064795892, COSV57873444; ClinVar: not provided / likely pathogenic; called by muse, varscan2
- DNAH11 | c.6004C>T p.R2002* | Nonsense Mutation (SNP) | VAF 47/294 reads (16%) | catalogued as rs373844629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- F8 | c.5593G>T p.D1865Y | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28933678, CM960560, CM960561, COSV64279265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 16/420 reads (4%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2
- FKBP10 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as rs372896892, CM119703; ClinVar: pathogenic; called by mutect2, varscan2
- GLA | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 53/149 reads (36%) | catalogued as rs104894841, CM930329, COSV54510711; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as rs1554646529, COSV58685784; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- GLI1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381253752, COSV57357760; called by muse, mutect2
- GUCY2C | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs587784572, CM155720, COSV53787172; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IFIH1 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587777448, CM144546, COSV55125315; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16342C>T p.R5448* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs1422752351, CM114906, COSV56418474; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MMADHC | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 57/190 reads (30%) | catalogued as rs118204047, CM081191, COSV57574342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | hotspot (GDC flag); catalogued as rs63751411, CM981314, COSV51876952; ClinVar: pathogenic; called by muse, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 66/339 reads (19%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 30/183 reads (16%) | catalogued as rs1057516414, CM141333, COSV62635208; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NR3C2 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121912573, CM065346, CM124521, COSV61000655; ClinVar: pathogenic; called by muse, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 25/179 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2
- PIK3CA | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 28/99 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 51/256 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1064793249, COSV55026579; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 52/186 reads (28%) | catalogued as rs794726799, CM067015, COSV57667265; ClinVar: pathogenic; called by muse, varscan2
- SCN5A | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs137854611, CM020302, CM024639, COSV100351382, COSV61142041; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 70/389 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TSC22D2 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 60/287 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62622374, COSV62622441; called by muse, mutect2, varscan2
- A2M | c.2920G>T p.E974* | Nonsense Mutation (SNP) | VAF 6/91 reads (7%) | catalogued as COSV100588671; called by muse, mutect2
- A2M | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1259395599, COSV59385400; called by muse, mutect2, varscan2
- A2M | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV59393078; called by muse, mutect2, varscan2
- A2ML1 | c.3458G>T p.R1153I | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100229590; called by muse, mutect2
- A2ML1 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1388303934, COSV55285428; called by muse, mutect2
- A4GNT | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV52630085; called by muse, mutect2, varscan2
- AADAC | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV51761634; called by muse, mutect2
- AADACL4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs139261871; called by muse, mutect2, varscan2
- AASDH | c.1484A>C p.E495A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs763378158, COSV52711111; called by muse, mutect2, varscan2
- ABCA1 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs551884479, CM1210656, COSV66064183; called by muse, mutect2, varscan2
- ABCA1 | c.2339G>A p.S780N | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143626002; called by muse, mutect2, varscan2
- ABCA10 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs745423957, COSV52230478; called by muse, mutect2, varscan2
- ABCA12 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55954144; called by muse, varscan2
- ABCA5 | c.3688A>C p.K1230Q | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV67017929, COSV67019351; called by muse, mutect2, varscan2
- ABCA5 | c.259A>C p.I87L | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV67019356; called by muse, mutect2, varscan2
- ABCA6 | c.4160C>T p.A1387V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs527461596, COSV52641428; called by muse, mutect2
- ABCA6 | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as COSV52637805; called by muse, mutect2
- ABCA8 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs768333090, COSV52197981; called by muse, mutect2
- ABCA8 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV52201741; called by muse, mutect2, varscan2
- ABCB1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199551851, COSV55945290, COSV55947749; called by muse, mutect2, varscan2
- ABCB1 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV55950310; called by muse, mutect2, varscan2
- ABCB11 | c.3716T>C p.I1239T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55602496; called by muse, mutect2, varscan2
- ABCB5 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV51722166; called by muse, mutect2
- ABCB7 | c.1253T>G p.F418C (on ENST00000373394 / NM_001271696.3; = p.F419C on NM_004299.6) | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53724248; called by muse, mutect2, varscan2
- ABCC12 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV60918731; called by muse, mutect2, varscan2
- ABCC4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs1415738240, COSV65313177; called by muse, mutect2, varscan2
- ABCD2 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58055535; called by muse, mutect2, varscan2
- ABCD3 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 11/246 reads (4%) | catalogued as rs1299713122; called by muse, mutect2
- ABCD3 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757515840, COSV64644762; called by muse, mutect2, varscan2
- ABCG4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1410189384, COSV56646016; called by muse, mutect2, varscan2
- ABHD17C | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as rs200549811, COSV51917334, COSV51918242; called by muse, mutect2
- ABHD2 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV61776563; called by muse, mutect2
- ABHD4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755342789, COSV53530796; called by muse, mutect2, varscan2
- ABHD4 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs368142560; called by muse, varscan2
- ABL2 | c.2050G>A p.E684K (on ENST00000502732 / NM_007314.4; = p.E669K on NM_005158.5) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV61012829; called by muse, mutect2, varscan2
- ABT1 | c.292A>C p.K98Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.216); catalogued as COSV51293449; called by muse, mutect2, varscan2
- AC004922.1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1032525792, COSV53559564; called by muse, mutect2, varscan2
- ACAD11 | c.1212C>A p.F404L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.586); catalogued as COSV53901135; called by muse, varscan2
- ACAN | c.5317C>A p.L1773I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.661); catalogued as rs767359295, COSV61357916, COSV61369764; called by muse, mutect2, varscan2
- ACBD3 | c.373A>C p.N125H | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64731384; called by muse, mutect2, varscan2
- ACBD6 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.849); catalogued as rs762191597, COSV62575798; called by muse, mutect2, varscan2
- ACCS | c.1250G>T p.R417I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV55460532; called by muse, mutect2, varscan2
- ACER1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as rs759458903, COSV56836321; called by muse, mutect2, varscan2
- ACLY | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV59863227; called by muse, mutect2, varscan2
- ACO1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV59385325; called by muse, varscan2
- ACOT12 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56897277; called by muse, mutect2, varscan2
- ACRBP | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 3/7 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV57525563; called by muse, mutect2
- ACSBG1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV51911410; called by muse, mutect2, varscan2
- ACSBG2 | c.738C>T p.N246= | Splice Region (SNP) | VAF 31/150 reads (21%) | catalogued as rs560299046, COSV53123538; called by muse, mutect2, varscan2
- ACSL1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV55666927; called by muse, mutect2, varscan2
- ACSL1 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55666940; called by muse, mutect2, varscan2
- ACSL4 | c.2117G>A p.R706Q (on ENST00000340800 / NM_022977.2; = p.R665Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as COSV61615679; called by muse, mutect2
- ACSM1 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54638199; called by muse, mutect2, varscan2
- ACSM2B | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 818/1368 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs200183083, COSV61656541; called by muse, mutect2, varscan2
- ACSS2 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs757812388, COSV53628675; called by muse, mutect2, varscan2
- ACSS3 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 22/134 reads (16%) | catalogued as rs776097345, COSV54091174; called by muse, mutect2, varscan2
- ACTL6A | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 82/409 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV66999539; called by muse, mutect2, varscan2
- ACTN2 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as rs1357678813, COSV63978576; called by muse, mutect2, varscan2
- ACTRT1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100947781, COSV64419695; called by muse, mutect2
- ACVR2B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs770339569, COSV61701613; called by mutect2, varscan2
- ADAD1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs13106730, COSV56641069; called by mutect2, varscan2
- ADAM12 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100901219, COSV64115506, COSV64116287; called by muse, mutect2, varscan2
- ADAM17 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1398583399, COSV60402089; called by muse, mutect2, varscan2
- ADAM2 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 57/268 reads (21%) | catalogued as COSV55860650, COSV55869098; called by muse, mutect2, varscan2
- ADAM21 | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50813258; called by muse, varscan2
- ADAM21 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 56/372 reads (15%) | catalogued as COSV50812063, COSV50813379; called by muse, varscan2
- ADAM22 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.07); catalogued as rs779354391, COSV55990094; called by muse, mutect2
- ADAM28 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV56106151; called by muse, mutect2, varscan2
- ADAM28 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV56106160; called by muse, mutect2, varscan2
- ADAM7 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 174/916 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs137990671, COSV51537987; called by muse, mutect2, varscan2
- ADAMTS12 | c.4668G>T p.K1556N | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV61260583; called by muse, mutect2, varscan2
- ADAMTS12 | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV100711500, COSV61257474, COSV61281671; called by muse, varscan2
- ADAMTS12 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.28); catalogued as rs563669246, COSV100711796, COSV61255980; called by muse, varscan2
- ADAMTS12 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.669); catalogued as COSV61281689; called by muse, mutect2, varscan2
- ADAMTS16 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56983360, COSV57008597; called by muse, mutect2, varscan2
- ADAMTS18 | c.1145G>T p.R382I | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51402028; called by muse, mutect2, varscan2
- ADAMTS19 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as COSV50805176; called by muse, mutect2, varscan2
- ADAMTS19 | c.3555G>T p.K1185N | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV50805247; called by muse, mutect2
- ADAMTS20 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs538139197, COSV67140479; called by muse, mutect2, varscan2
- ADAMTS5 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.501); catalogued as rs367992476, COSV53177630; called by mutect2, varscan2
- ADAMTS9 | c.4837G>A p.E1613K | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs749861523, COSV55791840; called by muse, mutect2, varscan2
- ADAMTS9 | c.4391G>A p.R1464Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1017604051; called by muse, mutect2, varscan2
- ADAMTS9 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1464529267, COSV55785517; called by muse, mutect2
- ADAR | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs767879893, COSV52712701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCK2 | c.1348A>C p.N450H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50783795; called by muse, mutect2
- ADCY8 | c.3500C>T p.T1167M | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356343883, COSV53897190; called by muse, mutect2, varscan2
- ADCY8 | c.1835G>T p.R612I | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV53928701, COSV53930321; called by muse, mutect2
- ADGRA3 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs776366061, COSV57546319; called by muse, mutect2, varscan2
- ADGRB3 | c.2741T>G p.L914R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53253084; called by muse, varscan2
- ADGRE1 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs145287041; called by muse, varscan2
- ADGRE1 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51672708, COSV51674277; called by muse, varscan2
- ADGRF5 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.616); catalogued as rs1196481373, COSV51930188; called by muse, mutect2, varscan2
- ADGRF5 | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200682859, COSV51930087; called by muse, mutect2, varscan2
- ADGRG2 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.411); catalogued as COSV61341636; called by muse, mutect2, varscan2
- ADGRG4 | c.2207T>A p.F736Y | Missense Mutation (SNP) | VAF 236/593 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54958376, COSV99797404; called by muse, mutect2, varscan2
- ADGRG4 | c.7010G>A p.S2337N | Missense Mutation (SNP) | VAF 163/321 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1195559174, COSV54968242; called by muse, mutect2, varscan2
- ADGRL1 | c.3359G>A p.R1120H (on ENST00000340736 / NM_001008701.3; = p.R1115H on NM_014921.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.174); catalogued as rs1568565676; called by muse, mutect2, varscan2
- ADGRL2 | c.3424G>T p.D1142Y (on ENST00000370717 / NM_001366005.1; = p.D1129Y on NM_012302.4) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54691626, COSV99588253; called by muse, mutect2, varscan2
- ADGRL3 | c.1511G>T p.G504V (on ENST00000506720 / NM_001322402.2; = p.G436V on NM_015236.6) | Missense Mutation (SNP) | VAF 96/571 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV72232082; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, mutect2, varscan2
- ADGRV1 | c.3224T>G p.F1075C | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV67996453; called by muse, mutect2, varscan2
- ADGRV1 | c.13424A>G p.D4475G | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV67996454; called by muse, mutect2
- ADGRV1 | c.18121T>C p.S6041P | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67996456; called by muse, mutect2, varscan2
- ADHFE1 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52559574; called by muse, mutect2, varscan2
- ADIPOQ | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.334); catalogued as rs1395173605, COSV100292270; called by muse, mutect2
- ADSL | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.584); catalogued as rs745787396, COSV53410811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADSL | c.358-5C>T | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as rs769856337, COSV53408962; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADSS2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 87/250 reads (35%) | catalogued as COSV63694640, COSV63695668; called by muse, mutect2, varscan2
- AFF1 | c.3004G>T p.G1002* | Nonsense Mutation (SNP) | VAF 35/151 reads (23%) | catalogued as COSV57124986; called by muse, mutect2, varscan2
- AFF2 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as COSV60682973; called by muse, mutect2
- AFF2 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV54009382; called by muse, mutect2, varscan2
- AFF3 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875692; called by muse, mutect2, varscan2
- AFG1L | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs944399722, COSV64558646; called by muse, mutect2, varscan2
- AFG3L2 | c.2132G>T p.R711I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1399438718, COSV52312988, COSV52316117; called by muse, mutect2, varscan2
- AGAP1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58325321; called by muse, mutect2, varscan2
- AGBL2 | c.2529A>C p.R843S | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as COSV54095909; called by muse, mutect2, varscan2
- AGBL4 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs752378443, COSV61896203; called by mutect2, varscan2
- AGBL5 | c.2606C>A p.P869H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV64080925; called by muse, mutect2, varscan2
- AGFG1 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV59515073; called by muse, mutect2, varscan2
- AGTR2 | c.536T>G p.F179C | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64157149; called by muse, mutect2
- AHNAK | c.7799C>A p.S2600Y | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57208598, COSV57232904; called by muse, mutect2, varscan2
- AHNAK2 | c.13756G>A p.D4586N | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs559049528, COSV60917301; called by muse, mutect2, varscan2
- AK5 | c.1283T>G p.I428S (on ENST00000354567 / NM_174858.3; = p.I402S on NM_012093.4) | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs143683857, COSV60982521; called by muse, mutect2, varscan2
- AK7 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774815872, COSV50876171; called by muse, mutect2, varscan2
- AK7 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs149622950, COSV50869271, COSV50871563; called by muse, mutect2, varscan2
- AK7 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50876091, COSV50884061; called by muse, mutect2, varscan2
- AK9 | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58143321; called by muse, mutect2, varscan2
- AK9 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as rs201060409, COSV53424497; called by muse, mutect2, varscan2
- AKAP3 | c.1533G>T p.E511D | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV57414796; called by muse, mutect2
- AKAP6 | c.1308A>C p.K436N | Missense Mutation (SNP) | VAF 193/506 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55235316; called by muse, mutect2, varscan2
- AKAP6 | c.3582G>T p.K1194N | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55235330; called by muse, mutect2, varscan2
- AKAP9 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV62358986; called by muse, mutect2
- AKAP9 | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277410775, COSV62358994; called by muse, mutect2, varscan2
- AKAP9 | c.10321C>T p.R3441C (on ENST00000359028; = p.R3417C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs146495719; ClinVar: likely benign; called by muse, varscan2
- AKAP9 | c.11495A>G p.E3832G (on ENST00000359028; = p.E3808G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99134188; called by muse, mutect2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALG10 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56794369; called by muse, varscan2
- ALG10 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 85/429 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56794380; called by muse, mutect2, varscan2
- ALG2 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53058670; called by muse, varscan2
- ALK | c.4319C>T p.A1440V | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV66578548; called by muse, mutect2
- ALLC | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs756768853, COSV52998569; called by mutect2, varscan2
- ALLC | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV52998585; called by muse, mutect2, varscan2
- ALMS1 | c.3369T>G p.I1123M | Missense Mutation (SNP) | VAF 124/401 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV52523205; called by muse, varscan2
- ALOX15B | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs753001193, COSV66480245; called by muse, mutect2, varscan2
- ALOXE3 | c.363T>G p.I121M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV59078278; called by muse, mutect2, varscan2
- ALPK2 | c.5042C>T p.A1681V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs758281980, COSV64490174; called by muse, varscan2
- ALPK2 | c.2513T>C p.V838A | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV64497718; called by muse, mutect2, varscan2
- ALPK2 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV64497726; called by muse, mutect2, varscan2
- ALS2 | c.2363C>A p.S788Y | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV51893456; called by muse, mutect2
- ALS2 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV51893464; called by muse, mutect2, varscan2
- AMBP | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768762324; called by muse, mutect2, varscan2
- AMDHD1 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 124/178 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV57140655, COSV99900529; called by muse, mutect2, varscan2
- AMFR | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.297); catalogued as rs750744117, COSV51924688; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMIGO2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs865785572, COSV56975699; called by muse, mutect2, varscan2
- AMOTL1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV58566090; called by muse, mutect2, varscan2
- AMPD1 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV62416866; called by muse, mutect2, varscan2
- AMPH | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV57759094; called by muse, mutect2, varscan2
- AMPH | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs151055033; called by muse, varscan2
- AMY1C | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100915248, COSV64407089; called by muse, mutect2, varscan2
- ANAPC4 | c.463A>C p.I155L | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59544154, COSV59546522; called by muse, mutect2, varscan2
- ANGEL2 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.03); catalogued as rs1255078851, COSV64738469; called by muse, mutect2, varscan2
- ANGPTL2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs191786568, COSV52233848; called by mutect2, varscan2
- ANK1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs376057905, COSV55880088; called by muse, mutect2, varscan2
- ANK2 | c.9145C>T p.R3049W | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201870166, COSV52158351; called by muse, mutect2
- ANK2 | c.10823C>A p.S3608Y | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52191449, COSV52191674; called by muse, mutect2, varscan2
- ANK3 | c.12320-1G>T p.X4107_splice (on ENST00000280772 / NM_001320874.2; = p.X628_splice on NM_001149.3) | Splice Site (SNP) | VAF 58/183 reads (32%) | catalogued as COSV99782726; called by muse, mutect2, varscan2
- ANK3 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769188895, COSV55084703; called by muse, mutect2
- ANKFN1 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59461168; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6059C>A p.S2020Y | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV51859752; called by muse, mutect2, varscan2
- ANKIB1 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as rs1205246827, COSV56066547; called by muse, mutect2, varscan2
- ANKRD12 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50845904; called by muse, mutect2
- ANKRD13C | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); catalogued as rs774093011, COSV52035716; called by muse, mutect2, varscan2
- ANKRD17 | c.3220G>T p.D1074Y | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV58228585; called by muse, mutect2, varscan2
- ANKRD26 | c.5045C>A p.S1682Y | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV65778762; called by muse, mutect2, varscan2
- ANKRD26 | c.4208A>G p.K1403R | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.121); catalogued as COSV65778767; called by muse, varscan2
- ANKRD26 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as rs754587473, COSV65778772; called by muse, varscan2
- ANKRD27 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138767777; called by muse, mutect2, varscan2
- ANKRD30B | c.1721C>A p.S574Y | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); catalogued as COSV100746798, COSV62824700; called by muse, mutect2, varscan2
- ANKRD45 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 150/364 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372141282; called by muse, mutect2, varscan2
- ANKRD50 | c.3568T>G p.S1190A | Missense Mutation (SNP) | VAF 113/568 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as COSV72386375; called by muse, mutect2, varscan2
- ANKRD52 | c.2409T>G p.H803Q | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV57287810; called by muse, mutect2, varscan2
- ANKS1B | c.2735C>T p.S912L (on ENST00000547776 / NM_152788.4; = p.S138L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60357807; called by muse, mutect2, varscan2
- ANKZF1 | c.2088A>C p.Q696H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV55479315; called by muse, mutect2, varscan2
- ANLN | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs767615862, COSV56074340; called by muse, mutect2, varscan2
- ANO4 | c.419G>T p.R140I (on ENST00000392977 / NM_001286615.2; = p.R105I on NM_178826.4) | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as rs1442864160, COSV54592395; called by muse, mutect2
- ANO4 | c.925C>T p.R309* (on ENST00000392977 / NM_001286615.2; = p.R274* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 18/318 reads (6%) | catalogued as rs866684439, COSV104407411, COSV54586554; called by muse, mutect2
- ANTXR2 | c.390A>C p.Q130H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55021434; called by muse, mutect2, varscan2
- ANXA2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV60318953; called by muse, mutect2, varscan2
- AP1G1 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs745889361, COSV55495894; called by muse, mutect2, varscan2
- AP4E1 | c.3090C>A p.F1030L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55920569; called by muse, mutect2, varscan2
- APAF1 | c.1539A>C p.K513N (on ENST00000551964 / NM_181861.2; = p.K502N on NM_001160.3) | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59669009; called by muse, mutect2, varscan2
- APBB1 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 37/123 reads (30%) | catalogued as COSV54974409; called by muse, mutect2, varscan2
- APBB1IP | c.534C>T p.L178= | Splice Region (SNP) | VAF 16/88 reads (18%) | catalogued as rs143340134; called by muse, mutect2, varscan2
- APBB1IP | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66136749; called by muse, mutect2, varscan2
- APC | c.3842C>A p.S1281* | Nonsense Mutation (SNP) | VAF 68/186 reads (37%) | catalogued as CM106371, COSV57326196, COSV57330499; called by muse, mutect2, varscan2
- APC | c.6575A>C p.K2192T | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57386832; called by muse, varscan2
- APLP1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1475297217, COSV55703883; called by muse, mutect2, varscan2
- APOB | c.10268T>C p.V3423A | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761983757, COSV51954951; called by muse, mutect2, varscan2
- APOB | c.9450C>A p.F3150L | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV51950504; called by muse, varscan2
- APOB | c.8297C>A p.S2766Y | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51954977; called by muse, mutect2, varscan2
- APOB | c.4400C>T p.A1467V | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV51955005; called by muse, varscan2
- APOB | c.1284G>T p.E428D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV51955038; called by muse, mutect2, varscan2
- APPBP2 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 38/181 reads (21%) | catalogued as COSV50030105; called by muse, varscan2
- APPL1 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs746072561, COSV55703838; called by muse, mutect2, varscan2
- ARAP3 | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53355321; called by muse, mutect2, varscan2
- ARFGAP3 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.413); catalogued as COSV54314814; called by muse, mutect2, varscan2
- ARFGEF1 | c.5491G>A p.G1831R | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs750537195, COSV51583453; called by muse, mutect2, varscan2
- ARFGEF1 | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 44/277 reads (16%) | catalogued as COSV51604329; called by muse, mutect2
- ARFGEF2 | c.3550C>A p.L1184M | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64215569; called by muse, mutect2, varscan2
- ARFIP1 | c.811C>T p.R271C (on ENST00000353617 / NM_001287432.1; = p.R239C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776711621, COSV61886462; called by muse, mutect2, varscan2
- ARG2 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1566803283, COSV55777318; called by muse, mutect2, varscan2
- ARHGAP12 | c.1884A>C p.K628N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60966707; called by muse, mutect2, varscan2
- ARHGAP17 | c.54-1G>T p.X18_splice | Splice Site (SNP) | VAF 10/91 reads (11%) | catalogued as COSV51506749, COSV99254153; called by muse, mutect2, varscan2
- ARHGAP20 | c.2598G>T p.K866N | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.432); catalogued as COSV52820030; called by muse, mutect2, varscan2
- ARHGAP20 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as rs751094122, COSV52808873; called by muse, mutect2, varscan2
- ARHGAP20 | c.1193T>C p.F398S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52820049; called by muse, varscan2
- ARHGAP24 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67846187; called by muse, mutect2
- ARHGAP32 | c.3757G>A p.E1253K (on ENST00000310343 / NM_001378025.1; = p.E904K on NM_014715.4) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.174); catalogued as rs768865360, COSV59847417; called by muse, varscan2
- ARHGAP35 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68336077; called by muse, mutect2, varscan2
- ARHGAP36 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs777932916, COSV52272714; called by muse, mutect2, varscan2
- ARHGEF12 | c.2437T>C p.F813L | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63107615; called by muse, mutect2
- ARHGEF15 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1362528188, COSV62726799; called by muse, mutect2, varscan2
- ARHGEF26 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs757436159; called by muse, mutect2, varscan2
- ARHGEF26 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs571135932, COSV62852509; called by muse, mutect2, varscan2
- ARHGEF4 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV58131016; called by muse, mutect2, varscan2
- ARHGEF5 | c.1146G>T p.W382C | Missense Mutation (SNP) | VAF 62/520 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99283261; called by muse, mutect2, varscan2
- ARID2 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57615816; called by muse, mutect2, varscan2
- ARID3B | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV60559310; called by mutect2, varscan2
- ARID4B | c.3063T>G p.N1021K | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV51611989; called by muse, mutect2, varscan2
- ARMC3 | c.715A>C p.K239Q | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV53068485; called by muse, varscan2
- ARMC4 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 14/143 reads (10%) | catalogued as rs1279559573, COSV53467729; called by muse, mutect2
- ARMC9 | c.1193T>G p.F398C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV63024066; called by muse, mutect2, varscan2
- ARMCX5 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 138/375 reads (37%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as COSV55767765; called by muse, mutect2, varscan2
- ARMH3 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV64238487; called by muse, mutect2, varscan2
- ARMT1 | c.1029T>A p.C343* | Nonsense Mutation (SNP) | VAF 38/180 reads (21%) | catalogued as COSV66179163; called by muse, mutect2, varscan2
- ARNTL | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs949259189, COSV62988189; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, mutect2, varscan2
- ARSB | c.361T>G p.C121G | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as CM160645; called by muse, mutect2
- ARSG | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs778128173, COSV71593687; called by muse, mutect2, varscan2
- ART4 | c.475T>G p.L159V | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57453422; called by muse, mutect2, varscan2
- ASAP1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.885); catalogued as rs759521913, COSV63046024; called by muse, mutect2, varscan2
- ASF1A | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57648147, COSV57648957; called by muse, mutect2, varscan2
- ASIC5 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 76/449 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs142024528; called by muse, mutect2, varscan2
- ASPM | c.8622A>C p.Q2874H | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as COSV99661229; called by muse, mutect2
- ASPM | c.7258T>C p.S2420P | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); catalogued as COSV54139786; called by muse, mutect2
- ASPM | c.6412A>G p.T2138A | Missense Mutation (SNP) | VAF 92/367 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1372714173, COSV54139795; called by muse, mutect2, varscan2
- ASPM | c.4400C>T p.S1467F | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54139808, COSV99660879; called by muse, mutect2
- ASXL2 | c.711A>C p.K237N | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV55468765; called by muse, mutect2, varscan2
- ASZ1 | c.1055+2T>C p.X352_splice | Splice Site (SNP) | VAF 61/213 reads (29%) | catalogued as COSV99498359; called by muse, mutect2, varscan2
- ASZ1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99498360; called by muse, mutect2
- ATAD2 | c.3808T>C p.C1270R | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1185968057, COSV54887372; called by muse, mutect2, varscan2
- ATAD2 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV54887386; called by muse, mutect2, varscan2
- ATE1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV56439668; called by muse, varscan2
- ATF6 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 90/476 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV63410389; called by muse, mutect2
- ATG16L1 | c.1108A>G p.T370A (on ENST00000392017 / NM_030803.7; = p.T351A on NM_017974.4) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61468292, COSV61468423; called by muse, mutect2, varscan2
- ATG16L1 | c.1414C>T p.R472C (on ENST00000392017 / NM_030803.7; = p.R453C on NM_017974.4) | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61468059; called by muse, mutect2, varscan2
- ATG2B | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 48/244 reads (20%) | catalogued as COSV63426033; called by muse, mutect2, varscan2
- ATG4C | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 53/256 reads (21%) | catalogued as COSV58608836; called by muse, varscan2
- ATG4C | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV58608849; called by muse, varscan2
- ATIC | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs199518893, COSV52692257; called by muse, mutect2, varscan2
- ATM | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV53778503; called by muse, mutect2, varscan2
- ATM | c.6229C>A p.L2077I | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV53778521, COSV53783409; called by muse, mutect2, varscan2
- ATP10A | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs1200926843, COSV63525602; called by muse, mutect2, varscan2
- ATP11C | c.1838G>T p.R613I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs776753802, COSV59561860, COSV59563934; called by muse, mutect2, varscan2
- ATP11C | c.1378-1G>A p.X460_splice | Splice Site (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100558754; called by muse, mutect2, varscan2
- ATP12A | c.2171A>G p.D724G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54524194; called by muse, mutect2, varscan2
- ATP1A2 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs1409103763, COSV63405744; called by muse, mutect2, varscan2
- ATP2A2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV58048028; called by muse, mutect2, varscan2
- ATP2A2 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1201260065, COSV57876442; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B1 | c.3130T>C p.S1044P | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53813659; called by muse, mutect2, varscan2
- ATP2C1 | c.1672A>G p.T558A | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV60763345; called by muse, mutect2, varscan2
- ATP5PB | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs11553277, COSV71953300; called by muse, varscan2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by muse, mutect2, varscan2
- ATP6V0D2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 25/162 reads (15%) | catalogued as COSV53416678, COSV53418240; called by muse, mutect2, varscan2
- ATP6V1E2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs773871657, COSV60576722; called by muse, mutect2, varscan2
- ATP8A1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372884316; called by muse, mutect2, varscan2
- ATP8B4 | c.2663T>G p.F888C | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV52725554; called by muse, mutect2, varscan2
- ATP8B4 | c.1524C>A p.F508L | Missense Mutation (SNP) | VAF 82/482 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52725563; called by muse, mutect2, varscan2
- ATP8B4 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs945620225, COSV52724140; called by muse, mutect2
- ATRX | c.7157G>A p.R2386Q | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100971556; called by muse, mutect2, varscan2
- ATRX | c.6666G>T p.K2222N | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV100971550, COSV100971557; called by muse, mutect2
- ATXN2L | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV57379874; called by muse, mutect2, varscan2
- ATXN7 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV55749939; called by muse, mutect2
- ATXN7 | c.752+2T>C p.X251_splice | Splice Site (SNP) | VAF 35/161 reads (22%) | catalogued as COSV99895464; called by muse, mutect2, varscan2
- AUTS2 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV61432380; called by muse, mutect2, varscan2
- AWAT2 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52144750; called by muse, mutect2, varscan2
- AXDND1 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62639258, COSV62649423; called by muse, mutect2, varscan2
- AXDND1 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766225252, COSV62639335; called by muse, mutect2, varscan2
- B3GALT2 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV66464589; called by muse, mutect2, varscan2
- B3GALT2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs751156224, COSV66463997; called by muse, varscan2
- B4GALT5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as rs369508203; called by muse, mutect2, varscan2
- BAALC | c.305G>A p.R102Q (on ENST00000297574 / NM_001364874.1; = p.R67Q on NM_024812.3) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); catalogued as rs200984161; called by muse, mutect2, varscan2
- BAALC | c.528G>T p.K176N (on ENST00000297574 / NM_001364874.1; = p.K141N on NM_024812.3) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV52565409; called by muse, mutect2
- BACE1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs138644093; called by muse, mutect2
- BAZ1A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs527680155, COSV62412314; called by muse, mutect2, varscan2
- BAZ1B | c.842A>C p.K281T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV59994934; called by muse, mutect2, varscan2
- BAZ1B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1554575752, COSV59989118; called by muse, mutect2, varscan2
- BAZ2A | c.4606C>T p.R1536W | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs750120430, COSV51644620; called by muse, mutect2, varscan2
- BAZ2A | c.3227T>C p.V1076A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs775845435, COSV51644645; called by muse, mutect2, varscan2
- BBS2 | c.940+2T>C p.X314_splice | Splice Site (SNP) | VAF 82/304 reads (27%) | catalogued as COSV99802905; called by muse, varscan2
- BBS2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs150572808; called by muse, varscan2
- BBX | c.1117T>G p.F373V | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1381702570, COSV57895934; called by muse, mutect2, varscan2
- BCL2L13 | c.219A>C p.E73D | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs568678964, COSV58227913; called by muse, mutect2, varscan2
- BCL9 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782706803, COSV52350740; called by muse, mutect2
- BCLAF1 | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 73/376 reads (19%) | catalogued as COSV62146254; called by muse, mutect2, varscan2
- BDP1 | c.3862G>T p.E1288* | Nonsense Mutation (SNP) | VAF 22/500 reads (4%) | catalogued as COSV62429210; called by muse, mutect2
- BEST2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV50378941; called by muse, mutect2, varscan2
- BICD2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.883); catalogued as rs761506224, COSV63551166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICRAL | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as rs780885776, COSV58408739; called by muse, mutect2, varscan2
- BIRC6 | c.12277G>T p.E4093* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV66042998; called by muse, mutect2, varscan2
- BIRC6 | c.14174G>A p.R4725Q | Missense Mutation (SNP) | VAF 88/428 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as COSV70198010; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1271G>T p.R424I | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV57279584; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1400329743, COSV63244190, COSV63244592; called by muse, varscan2
- BIVM-ERCC5 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 28/175 reads (16%) | catalogued as COSV63247633; called by muse, mutect2, varscan2
- BLID | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV73340095; called by muse, mutect2
- BLM | c.3431G>T p.R1144I | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV61927820; called by muse, mutect2, varscan2
- BMP6 | c.1227A>C p.K409N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV51672929; called by mutect2, varscan2
- BMPER | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV51832711; called by muse, mutect2, varscan2
- BMPR1B | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52782410; called by muse, mutect2, varscan2
- BMPR1B | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 24/125 reads (19%) | catalogued as COSV52782425; called by muse, varscan2
- BMPR1B | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.534); catalogued as COSV52782447; called by muse, varscan2
- BMPR2 | c.2510A>G p.N837S | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV65813796; called by muse, varscan2
- BMX | c.1371C>A p.F457L | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754428384, COSV59590089; called by muse, mutect2, varscan2
- BNC1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs146647716; called by muse, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BNIP5 | c.482A>G p.H161R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV71325882; called by muse, mutect2, varscan2
- BPIFB1 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53609060; called by muse, mutect2, varscan2
- BPTF | c.5876G>A p.R1959Q | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs556375365, COSV58848081; called by muse, mutect2, varscan2
- BRCA2 | c.996T>G p.I332M | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV66463357; called by muse, mutect2, varscan2
- BRCA2 | c.6473T>G p.F2158C | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV66463360; called by muse, mutect2, varscan2
- BRCA2 | c.9253A>G p.T3085A | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as CD121947, COSV66454758, COSV66463364; called by muse, mutect2, varscan2
- BRD7 | c.591+2T>C p.X197_splice | Splice Site (SNP) | VAF 38/217 reads (18%) | catalogued as COSV101165076; called by muse, mutect2, varscan2
- BRD8 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs372286313; called by muse, mutect2
- BRD8 | c.1822T>C p.S608P (on ENST00000254900 / NM_139199.2; = p.S681P on NM_006696.4) | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as COSV50171450; called by muse, mutect2
- BRINP3 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV66524657; called by muse, varscan2
- BRIP1 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781321, CM1411623, COSV51998688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 34/124 reads (27%) | catalogued as COSV60903539; called by muse, mutect2, varscan2
- BRWD1 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58122834; called by muse, mutect2, varscan2
- BTAF1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200229615, COSV56436282; called by muse, varscan2
- BTAF1 | c.3722G>A p.R1241Q | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs762217759, COSV56440051; called by muse, mutect2, varscan2
- BTBD3 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV54780819; called by muse, mutect2, varscan2
- BTK | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940191, COSV58124056; called by muse, mutect2, varscan2
- BTK | c.526A>C p.K176Q | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV58124068; called by muse, mutect2, varscan2
- BTK | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV58124080; called by muse, mutect2, varscan2
- BTK | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs368549990, COSV58117893, COSV58121329; called by muse, mutect2
- BTN3A3 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1348988194, COSV55073989; called by muse, mutect2, varscan2
- BUB1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV57061159; called by muse, mutect2, varscan2
- BUD13 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs753401362, COSV52770718; called by muse, mutect2, varscan2
- C10orf120 | c.963T>G p.S321R | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV61492780; called by muse, mutect2, varscan2
- C11orf53 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV54721084, COSV54722562; called by muse, mutect2, varscan2
- C12orf40 | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV61138217; called by muse, mutect2, varscan2
- C12orf50 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100072373; called by muse, varscan2
- C14orf28 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57332835, COSV57334153; called by muse, mutect2, varscan2
- C16orf46 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV55153523; called by muse, mutect2, varscan2
- C1GALT1C1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58973706; called by muse, mutect2, varscan2
- C1QTNF1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs767734960, COSV59262440; called by muse, mutect2, varscan2
- C1orf100 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs906645188, COSV57374449; called by muse, varscan2
- C1orf112 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV53683241; called by muse, varscan2
- C2orf66 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV61099280; called by muse, mutect2, varscan2
- C3 | c.2487C>A p.F829L | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55569211; called by muse, mutect2, varscan2
- C3AR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs56297048, COSV50820555; called by muse, mutect2, varscan2
- C5 | c.5003C>T p.A1668V | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs765573116, COSV56332579; called by muse, mutect2, varscan2
- C5 | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs138933092; called by muse, mutect2, varscan2
- C5 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV56332594; called by muse, mutect2, varscan2
- C5 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544818019, COSV56326412; called by muse, varscan2
- C6 | c.550T>C p.Y184H | Missense Mutation (SNP) | VAF 66/369 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54719941; called by muse, mutect2, varscan2
- C7 | c.1765T>C p.F589L | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV57473442; called by muse, mutect2, varscan2
- C7orf25 | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); catalogued as COSV63274424; called by muse, mutect2, varscan2
- C9orf131 | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 115/523 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as COSV56614586; called by muse, mutect2, varscan2
- C9orf43 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99928650; called by muse, mutect2
- CACHD1 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51560641; called by muse, mutect2, varscan2
- CACHD1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs146843239; called by muse, mutect2, varscan2
- CACNA1A | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs371016637; called by mutect2, varscan2
- CACNA1A | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 87/392 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as CM163640, COSV64213842; called by muse, varscan2
- CACNA1C | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59778068; called by muse, mutect2
- CACNA1D | c.5786G>A p.R1929H (on ENST00000350061 / NM_001128840.3; = p.R1949H on NM_000720.4) | Missense Mutation (SNP) | VAF 68/80 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs371126105; called by muse, mutect2, varscan2
- CACNA1E | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62401217; called by muse, mutect2
- CACNA1E | c.3945C>A p.F1315L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV62431308; called by muse, mutect2, varscan2
- CACNA1E | c.6095C>T p.S2032L (on ENST00000367573 / NM_001205293.3; = p.S1989L on NM_000721.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs1049589906, COSV62395266; called by muse, mutect2, varscan2
- CACNB1 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60000537; called by muse, mutect2
- CAD | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs914121018, COSV53031320; called by muse, mutect2
- CADM2 | c.525G>T p.E175D (on ENST00000407528 / NM_001167674.2; = p.E177D on NM_153184.4) | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV67407777; called by muse, mutect2, varscan2
- CADPS | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV51905887; called by muse, mutect2, varscan2
- CADPS | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51905907; called by muse, mutect2
- CADPS | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV51905924; called by muse, mutect2, varscan2
- CALCR | c.1242C>A p.V414= (on ENST00000649521 / NM_001164737.2; = p.V398= on NM_001742.4) | Splice Region (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100810916, COSV64012461; called by muse, mutect2
- CALD1 | c.1994C>T p.S665L (on ENST00000361675 / NM_033138.4; = p.S410L on NM_004342.7) | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs1372249532, COSV62654897; called by muse, mutect2, varscan2
- CAMK1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs746723292, COSV56540563; called by muse, mutect2, varscan2
- CAMKMT | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558843249; called by muse, mutect2
- CAMKV | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56558081; called by muse, mutect2, varscan2
- CAMSAP2 | c.4324T>C p.Y1442H (on ENST00000236925 / NM_001297707.2; = p.Y1431H on NM_203459.3) | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558214116; called by muse, mutect2
- CAND1 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV73389799; called by muse, mutect2, varscan2
- CAPN13 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 110/494 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.326); catalogued as rs542792832, COSV54429633; called by muse, mutect2, varscan2
- CAPN5 | c.739G>A p.D247N (on ENST00000456580; = p.D207N on NM_004055.5) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.231); catalogued as rs367724731, COSV53687605; called by muse, mutect2, varscan2
- CAPN6 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136965; called by muse, mutect2, varscan2
- CAPN7 | c.390A>C p.K130N | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV53781035; called by muse, mutect2, varscan2
- CAPNS2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766790678, COSV50900476; called by muse, mutect2, varscan2
- CAPRIN2 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 57/333 reads (17%) | catalogued as COSV51834002; called by muse, varscan2
- CAPS2 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 11/171 reads (6%) | catalogued as COSV99060224; called by muse, mutect2
- CAPSL | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs199837654; called by muse, mutect2, varscan2
- CARMIL1 | c.3193C>T p.R1065W | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs753444416, COSV61524570; called by muse, mutect2, varscan2
- CASK | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV59376251; called by muse, mutect2, varscan2
- CASP5 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 102/517 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs543265797, COSV52829825; called by muse, mutect2
- CASP8AP2 | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as rs375610839; called by muse, mutect2, varscan2
- CASQ1 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1477223102, COSV100927375; called by muse, mutect2
- CATSPERB | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | catalogued as rs779893104, COSV56422429, COSV99831126; called by muse, mutect2, varscan2
- CAVIN3 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1028188353, COSV58268780; called by muse, mutect2, varscan2
- CAVIN4 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56868488; called by muse, mutect2, varscan2
- CBFB | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs761036715, COSV51996734, COSV51999572, COSV52001985; called by muse, mutect2, varscan2
- CBFB | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as COSV52001997; called by muse, mutect2, varscan2
- CBLB | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | catalogued as rs1476526903, COSV51430548; called by muse, mutect2
- CBR4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60371038; called by muse, mutect2, varscan2
- CCBE1 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67951716; called by muse, mutect2, varscan2
- CCDC105 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.19); catalogued as COSV52963221, COSV52965823; called by muse, mutect2
- CCDC112 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV65474076; called by muse, mutect2, varscan2
- CCDC136 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV52805903; called by muse, mutect2, varscan2
- CCDC14 | c.1795A>G p.T599A (on ENST00000488653; = p.T551A on NM_022757.5) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59948222; called by muse, varscan2
- CCDC141 | c.3796C>A p.L1266I | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV55383368; called by muse, mutect2
- CCDC141 | c.2206-1G>A p.X736_splice | Splice Site (SNP) | VAF 39/164 reads (24%) | catalogued as COSV99837606; called by muse, mutect2, varscan2
- CCDC144A | c.1390A>C p.N464H | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV100138730; called by muse, mutect2
- CCDC144A | c.2723G>T p.R908I | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV100138207; called by muse, mutect2
- CCDC144A | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs777407520, COSV60697225, COSV60699146; called by muse, mutect2, varscan2
- CCDC149 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1190356614, COSV60882467; called by muse, mutect2, varscan2
- CCDC157 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs750607091; called by mutect2, varscan2
- CCDC170 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 6/89 reads (7%) | catalogued as COSV99498032; called by muse, mutect2
- CCDC170 | c.1931A>C p.E644A | Missense Mutation (SNP) | VAF 83/335 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV53347007; called by muse, mutect2, varscan2
- CCDC174 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 28/146 reads (19%) | catalogued as COSV57980621, COSV99070631; called by muse, varscan2
- CCDC174 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs187313760; called by muse, varscan2
- CCDC178 | c.2317G>T p.E773* (on ENST00000383096 / NM_001105528.3; = p.E735* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as rs150180566; called by muse, mutect2, varscan2
- CCDC25 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as rs747557723, COSV62958328; called by muse, mutect2, varscan2
- CCDC30 | c.1397C>T p.T466I (on ENST00000340612; = p.T423I on NM_001080850.3) | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as COSV59609735; called by muse, mutect2, varscan2
- CCDC39 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1458123630, COSV56483732; called by muse, mutect2, varscan2
- CCDC51 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56494657; called by muse, mutect2, varscan2
- CCDC65 | c.420A>C p.E140D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV57198195; called by muse, mutect2, varscan2
- CCDC73 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58799590; called by muse, varscan2
- CCDC92 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs777304210, COSV99435221; called by muse, mutect2
- CCER1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100727100, COSV62647956; called by muse, mutect2
- CCHCR1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1173895969; called by muse, mutect2, varscan2
- CCHCR1 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as COSV66185222; called by muse, mutect2
- CCKBR | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58104557; called by muse, varscan2
- CCL14 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs771441014; called by muse, mutect2, varscan2
- CCN6 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100037228; called by muse, mutect2
- CCNB2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55596779; called by muse, mutect2, varscan2
- CCNY | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55191629; called by muse, mutect2, varscan2
- CCPG1 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV60527995; called by muse, mutect2, varscan2
- CCR1 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as rs1166195742, COSV56122205; called by muse, mutect2, varscan2
- CCR2 | c.944T>G p.L315R | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99432615; called by muse, mutect2
- CCR8 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 95/405 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV58337376; called by muse, mutect2, varscan2
- CD109 | c.3680G>T p.R1227L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV54650900, COSV54657900; called by muse, mutect2, varscan2
- CD163 | c.3302C>A p.S1101Y | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.896); catalogued as rs1250219603, COSV63134475, COSV63137975; called by muse, mutect2, varscan2
- CD163 | c.3008C>A p.S1003Y | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63131592, COSV63137983; called by muse, mutect2, varscan2
- CD163 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs766660196, COSV63131903; called by muse, mutect2, varscan2
- CD1E | c.993dup p.Q332Tfs*5 | Frame Shift Ins (INS) | VAF 14/107 reads (13%) | catalogued as rs866136574; called by mutect2, varscan2
- CD2 | c.141T>G p.S47R | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV65643778; called by muse, mutect2, varscan2
- CD22 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764854283; called by muse, mutect2, varscan2
- CD22 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202226815, COSV99323574; called by mutect2, varscan2
- CD226 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV54614674, COSV54616504, COSV99710753; called by muse, mutect2
- CD244 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59241989; called by muse, mutect2, varscan2
- CD3D | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as rs777721098, COSV56140079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD3G | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs201752677, COSV99416902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD40LG | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 57/752 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs371041193, CM970247, COSV101033445; ClinVar: uncertain significance; called by muse, mutect2
- CD72 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | catalogued as COSV52411772; called by muse, mutect2, varscan2
- CD99L2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs146802752, COSV60938757; called by muse, mutect2, varscan2
- CDC16 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV52958807; called by muse, mutect2, varscan2
- CDC16 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1272008863, COSV52962117; called by muse, mutect2, varscan2
- CDC23 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV101203113, COSV67510739; called by muse, mutect2, varscan2
- CDC42BPA | c.2085G>T p.K695N | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV100506730; called by muse, mutect2
- CDC42BPA | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV62023249; called by muse, mutect2, varscan2
- CDC42BPB | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs772636121, COSV63477099; called by mutect2, varscan2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, mutect2, varscan2
- CDCA7L | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770755131; called by muse, mutect2, varscan2
- CDCA8 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs187658080, COSV59238766; called by muse, mutect2, varscan2
- CDH1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs876660645, COSV55730544, COSV55733510, COSV55735767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.1573T>G p.F525V | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV52600042; called by muse, mutect2, varscan2
- CDH10 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.822); catalogued as rs138533676; called by muse, mutect2, varscan2
- CDH11 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51778990; called by muse, mutect2, varscan2
- CDH16 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV55340110; called by muse, mutect2, varscan2
- CDH17 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760876203, COSV50343788; called by muse, mutect2, varscan2
- CDH18 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs148450624, COSV56937399; called by muse, mutect2, varscan2
- CDH18 | c.434T>G p.F145C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56964783; called by muse, varscan2
- CDH19 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV50979948; called by muse, mutect2, varscan2
- CDH2 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52297947; called by muse, mutect2, varscan2
- CDH20 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53009145, COSV53014733; called by mutect2, varscan2
- CDH22 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs372135667; called by muse, mutect2, varscan2
- CDH3 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs868118578, COSV50577609; called by muse, mutect2, varscan2
- CDH8 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs762249948, COSV54865707, COSV54878044; called by muse, mutect2, varscan2
- CDH8 | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99076732; called by muse, varscan2
- CDH9 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50415316; called by muse, mutect2, varscan2
- CDK17 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as rs750936507, COSV54127953; called by muse, mutect2, varscan2
- CDK18 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs748768587, COSV63729044; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4208G>A p.R1403Q | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767034315, COSV62574308; called by muse, mutect2, varscan2
- CDON | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141611214; called by muse, mutect2, varscan2
- CDON | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145492265, COSV54998134; called by muse, mutect2, varscan2
- CEACAM21 | c.816C>A p.D272E (on ENST00000401445 / NM_001098506.4; = p.D271E on NM_033543.6) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV51816894; called by muse, mutect2, varscan2
- CELF6 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs761929086, COSV54717292; called by mutect2, varscan2
- CEMIP | c.2435G>A p.G812D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55001034; called by muse, mutect2, varscan2
- CEMIP2 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV65489859; called by muse, mutect2, varscan2
- CENPE | c.7952C>A p.S2651Y | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54391695, COSV99478723; called by muse, mutect2, varscan2
- CENPF | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 104/391 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV65279564; called by muse, mutect2, varscan2
- CENPF | c.6121G>A p.E2041K | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV65279572; called by muse, mutect2, varscan2
- CENPF | c.7807G>A p.D2603N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV65279580; called by muse, mutect2, varscan2
- CENPJ | c.3737C>T p.T1246M | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767833776, COSV55036267; called by muse, mutect2, varscan2
- CENPJ | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 63/263 reads (24%) | catalogued as rs763373509, COSV67883316; called by muse, mutect2, varscan2
- CENPK | c.291C>T p.F97= | Splice Region (SNP) | VAF 19/100 reads (19%) | catalogued as COSV54469818; called by muse, mutect2, varscan2
- CENPK | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 87/263 reads (33%) | catalogued as COSV54467811; called by muse, varscan2
- CENPM | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs763500522, COSV53246056; called by muse, mutect2
- CEP120 | c.2943A>C p.K981N | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1388103552, COSV60268965; called by muse, mutect2, varscan2
- CEP126 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV54827338, COSV54831336; called by muse, mutect2, varscan2
- CEP126 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs756185753, COSV54831351; called by muse, mutect2, varscan2
- CEP128 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs561372195, COSV53676499; called by muse, mutect2, varscan2
- CEP135 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748311087, COSV57263213, COSV99954855; called by muse, mutect2, varscan2
- CEP152 | c.2745A>C p.E915D | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV57865450; called by muse, mutect2, varscan2
- CEP152 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1453843365, COSV57861618; called by muse, mutect2, varscan2
- CEP170 | c.4207C>T p.R1403W | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747106206, COSV60515578; called by muse, mutect2, varscan2
- CEP170 | c.1273-8C>A | Splice Region (SNP) | VAF 8/128 reads (6%) | catalogued as COSV60508721; called by muse, mutect2
- CEP170 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60515593; called by mutect2, varscan2
- CEP20 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.388); catalogued as rs905421942, COSV55384157; called by muse, mutect2, varscan2
- CEP250 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs763406705, COSV61168241; called by mutect2, varscan2
- CEP290 | c.4394G>A p.R1465Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs576877716, COSV58356962; called by muse, mutect2, varscan2
- CEP57 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 36/243 reads (15%) | catalogued as rs778077296, COSV57690764; called by muse, mutect2, varscan2
- CEP57L1 | c.1059T>G p.S353R | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV61246428; called by muse, mutect2, varscan2
- CEP63 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59679780; called by muse, mutect2, varscan2
- CEP78 | c.2023A>G p.N675D (on ENST00000424347 / NM_001349840.2; = p.N676D on NM_032171.3) | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV52850756; called by muse, mutect2, varscan2
- CEP85L | c.1708A>C p.K570Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV63829133; called by muse, mutect2, varscan2
- CEP95 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV73609663; called by muse, mutect2, varscan2
- CER1 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101097776, COSV66604017; called by muse, mutect2, varscan2
- CERT1 | c.638G>A p.R213Q (on ENST00000405807 / NM_001130105.1; = p.R85Q on NM_005713.3) | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54665276; called by muse, mutect2, varscan2
- CFAP251 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1428337065, COSV56611369; called by muse, mutect2, varscan2
- CFAP43 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | catalogued as COSV53377997; called by muse, mutect2, varscan2
- CFAP43 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV53381798; called by muse, mutect2, varscan2
- CFAP44 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs370318076; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP53 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 51/196 reads (26%) | catalogued as COSV68352931; called by muse, mutect2, varscan2
- CFAP58 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV57213800; called by muse, mutect2, varscan2
- CFAP61 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs760689597, COSV55620168, COSV55632747; called by mutect2, varscan2
- CFHR4 | c.206A>G p.Y69C (on ENST00000367416 / NM_001201551.2; = p.Y70C on NM_006684.5) | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); catalogued as rs765896121, COSV52230234; called by muse, mutect2, varscan2
- CHAT | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as rs1442234888, COSV60334175; called by muse, mutect2, varscan2
- CHD3 | c.2031G>T p.K677N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV57881098; called by muse, mutect2, varscan2
- CHD7 | c.825C>A p.F275L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV71114560; called by muse, mutect2
- CHD9 | c.4888C>T p.R1630C | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1204735412; called by muse, mutect2
- CHD9 | c.8116A>C p.N2706H (on ENST00000398510 / NM_001382353.1; = p.N2690H on NM_025134.7) | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV54617270; called by muse, mutect2, varscan2
- CHGB | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.211); catalogued as COSV66761934; called by muse, mutect2, varscan2
- CHI3L1 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55140340; called by muse, mutect2, varscan2
- CHI3L2 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1039610150, COSV63874430; called by muse, mutect2, varscan2
- CHI3L2 | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs1239464290, COSV100869313, COSV63874292; called by muse, mutect2
- CHL1 | c.2584C>T p.P862S (on ENST00000397491 / NM_001253387.1; = p.P878S on NM_006614.4) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.095); catalogued as rs1048568442; called by muse, mutect2
- CHMP2A | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs376979258; called by mutect2, varscan2
- CHORDC1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 37/223 reads (17%) | catalogued as COSV100272155, COSV57706659; called by muse, mutect2, varscan2
- CHRM2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs768531848, COSV57767335, COSV57769152; called by muse, mutect2, varscan2
- CHRM3 | c.627C>A p.Y209* | Nonsense Mutation (SNP) | VAF 20/124 reads (16%) | catalogued as COSV55106645; called by muse, mutect2, varscan2
- CHRNA6 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 39/323 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs139568359, COSV52379861, COSV52381216; called by muse, mutect2, varscan2
- CHRNB1 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0.119); catalogued as COSV60142537; called by muse, mutect2, varscan2
- CHST11 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57995765; called by muse, mutect2, varscan2
- CHST9 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.447); catalogued as COSV52450361; called by muse, mutect2, varscan2
- CIART | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 36/211 reads (17%) | catalogued as COSV51746327, COSV99290205; called by mutect2, varscan2
- CIART | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV51746334; called by muse, mutect2
- CILK1 | c.156+2T>C p.X52_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100608088; called by muse, mutect2, varscan2
- CIR1 | c.69A>C p.K23N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55810169; called by muse, varscan2
- CIT | c.3184C>T p.R1062* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as COSV55884837; called by muse, mutect2, varscan2
- CLASP1 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55313295; called by muse, mutect2, varscan2
- CLCA1 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs772377825, COSV52331848; called by muse, mutect2, varscan2
- CLCA4 | c.160-1G>T p.X54_splice | Splice Site (SNP) | VAF 132/790 reads (17%) | catalogued as COSV99760862; called by muse, mutect2, varscan2
- CLCN1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 107/431 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs889073641, CM110545, COSV58368676; called by muse, mutect2, varscan2
- CLCN3 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61628748; called by muse, mutect2, varscan2
- CLDN10 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV65296963; called by muse, mutect2
- CLEC4C | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs759515484, COSV63582651, COSV63583304; called by muse, mutect2, varscan2
- CLEC4F | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV55481873, COSV99713604; called by muse, varscan2
- CLECL1 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV59932182; called by muse, mutect2, varscan2
- CLECL1 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs760774428, COSV59931174, COSV59931513; called by mutect2, varscan2
- CLIP1 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV56809291; called by muse, varscan2
- CLIP4 | c.1733G>T p.R578I | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV60753220; called by muse, mutect2, varscan2
- CLRN1 | c.588T>G p.F196L | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.266); catalogued as COSV55807049; called by muse, varscan2
- CLTC | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV52253625; called by muse, mutect2, varscan2
- CLTCL1 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs782055199, COSV54229794; called by muse, mutect2
- CMAS | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as rs753560501, COSV57556336; called by muse, mutect2, varscan2
- CMC4 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62900804; called by muse, mutect2, varscan2
- CMTR1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 129/218 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV65089699; called by muse, mutect2, varscan2
- CMYA5 | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV71409940; called by muse, mutect2, varscan2
- CMYA5 | c.3431C>A p.S1144* | Nonsense Mutation (SNP) | VAF 46/224 reads (21%) | catalogued as COSV71409946; called by muse, mutect2, varscan2
- CMYA5 | c.11558C>A p.S3853Y | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs907830031, COSV69746273; called by muse, mutect2, varscan2
- CNDP2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60841836; called by muse, mutect2, varscan2
- CNGA1 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV62054217, COSV62055971; called by muse, mutect2, varscan2
- CNGA4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV56415185; called by muse, mutect2, varscan2
- CNGB3 | c.1264T>G p.F422V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV60699294; called by muse, mutect2, varscan2
- CNMD | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV65034222; called by muse, mutect2, varscan2
- CNNM1 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs143111634; called by muse, mutect2, varscan2
- CNOT1 | c.4949G>A p.R1650Q | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55317545; called by muse, mutect2, varscan2
- CNOT10 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV59395740; called by muse, mutect2, varscan2
- CNOT11 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.175); catalogued as rs1383777591; called by muse, mutect2
- CNOT4 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as rs1308899779, COSV59651637; called by muse, mutect2, varscan2
- CNOT7 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV61352502; called by muse, varscan2
- CNPY1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); catalogued as rs1344924963, COSV58786479; called by muse, mutect2, varscan2
- CNTF | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs761605079, COSV60162305; called by muse, mutect2, varscan2
- CNTN1 | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1212527710, COSV61646232; called by muse, mutect2
- CNTN6 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.718); catalogued as COSV63191610; called by muse, mutect2
- CNTNAP4 | c.2516T>G p.F839C | Missense Mutation (SNP) | VAF 125/639 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56702670; called by muse, mutect2, varscan2
- CNTNAP5 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV70514569; called by muse, mutect2, varscan2
- CNTNAP5 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs369591290, COSV70510307; called by muse, mutect2, varscan2
- CNTRL | c.4135G>T p.E1379* | Nonsense Mutation (SNP) | VAF 43/215 reads (20%) | catalogued as COSV53054120; called by muse, mutect2, varscan2
- CNTROB | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV66607893, COSV66608066; called by muse, mutect2, varscan2
- COA8 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs756550363, COSV56029897; called by muse, mutect2, varscan2
- COBLL1 | c.2310A>C p.K770N (on ENST00000392717; = p.K732N on NM_014900.5) | Missense Mutation (SNP) | VAF 71/382 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52077169; called by muse, varscan2
- COG5 | c.187A>C p.K63Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as COSV51765777; called by muse, mutect2
- COG6 | c.803A>C p.E268A | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV62998429; called by muse, mutect2, varscan2
- COL12A1 | c.6074G>A p.R2025H | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs34336755; called by muse, mutect2
- COL12A1 | c.1487A>G p.K496R | Missense Mutation (SNP) | VAF 124/426 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59409410; called by muse, varscan2
- COL15A1 | c.4014C>A p.Y1338* | Nonsense Mutation (SNP) | VAF 64/280 reads (23%) | catalogued as COSV66649860; called by muse, mutect2, varscan2
- COL21A1 | c.1029G>A p.T343= | Splice Region (SNP) | VAF 7/35 reads (20%) | catalogued as rs373532211; called by muse, mutect2, varscan2
- COL21A1 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55158346; called by muse, mutect2, varscan2
- COL21A1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as COSV55182069; called by muse, mutect2
- COL27A1 | c.2069A>C p.K690T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61931201; called by muse, mutect2, varscan2
- COL4A1 | c.327A>C p.G109= | Splice Region (SNP) | VAF 30/184 reads (16%) | catalogued as COSV65432689; called by muse, mutect2, varscan2
- COL4A6 | c.1648C>A p.L550I | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV57860901; called by muse, mutect2, varscan2
- COL5A1 | c.1389G>A p.P463= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as rs1057518771, COSV65671787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs150401168; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.6511G>A p.G2171R | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55090010, COSV99797982; called by muse, mutect2, varscan2
- COL6A3 | c.6387G>T p.E2129D | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV55085998; called by muse, mutect2
- COL6A3 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762016120, COSV55112550; called by muse, mutect2, varscan2
- COL6A3 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55085019; called by muse, mutect2, varscan2
- COL6A6 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs201898554, COSV62023536; called by muse, mutect2, varscan2
- COL6A6 | c.2176C>A p.L726I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62039101; called by muse, mutect2, varscan2
- COL7A1 | c.8054G>A p.R2685Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886058630, COSV56477277; called by muse, varscan2
- COL9A1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 42/226 reads (19%) | catalogued as COSV57894300; called by muse, varscan2
- COLGALT2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777342761, COSV62298603; called by muse, varscan2
- COLGALT2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.087); catalogued as rs368641256, COSV62728112; called by muse, mutect2, varscan2
- COMMD2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779093793, COSV101519909, COSV71946699; called by muse, mutect2
- COMMD8 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as rs1275304908, COSV67500808; called by muse, mutect2, varscan2
- COP1 | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV58177340; called by muse, mutect2, varscan2
- COPB1 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.557); catalogued as COSV51450408; called by muse, mutect2
- COPB2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60813990; called by muse, mutect2, varscan2
- COPG1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767858436, COSV59112226; called by mutect2, varscan2
- COQ6 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs765468843, COSV53180408; called by muse, varscan2
- CORIN | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56700458; called by muse, mutect2, varscan2
- COX15 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.823); catalogued as COSV50013402; called by muse, mutect2, varscan2
- CPA1 | c.956A>C p.K319T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50576656; called by muse, mutect2, varscan2
- CPA3 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1429769999, COSV56044181; called by muse, mutect2, varscan2
- CPAMD8 | c.4327G>A p.A1443T (on ENST00000651564; = p.A1396T on NM_015692.5) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs780228887; called by muse, mutect2, varscan2
- CPB2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51673820; called by muse, mutect2
- CPD | c.3736G>T p.G1246C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56716744; called by muse, mutect2, varscan2
- CPE | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68582884; called by muse, mutect2, varscan2
- CPE | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.136); catalogued as rs1386168807, COSV68582887; called by muse, mutect2, varscan2
- CPEB3 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs747888308, COSV56463964; called by muse, mutect2, varscan2
- CPED1 | c.544A>C p.N182H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60012333; called by muse, mutect2, varscan2
- CPED1 | c.2996C>T p.S999L | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs201789315, COSV59997531, COSV59999791; called by muse, mutect2, varscan2
- CPNE4 | c.864C>G p.C288W | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV70199170, COSV70200731; called by muse, mutect2, varscan2
- CPNE6 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53747080; called by mutect2, varscan2
- CPNE8 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV58852942; called by muse, mutect2, varscan2
- CPNE9 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV56068061, COSV56068362; called by muse, mutect2
- CPQ | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs1259795110, COSV55162416; called by muse, mutect2, varscan2
- CPSF4 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs576966048, COSV52855730; called by muse, mutect2, varscan2
- CR1L | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 76/360 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.873); catalogued as COSV54331990, COSV99686643; called by muse, mutect2, varscan2
- CR2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs147633291; called by muse, mutect2
- CR2 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs545091003, COSV65509958; called by muse, mutect2, varscan2
- CRB1 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 108/337 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.037); catalogued as rs146120995; called by muse, mutect2, varscan2
- CREB1 | c.976A>G p.I326V (on ENST00000432329 / NM_134442.5; = p.I312V on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62067004; called by muse, varscan2
- CREBRF | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.011); catalogued as rs1378798752, COSV51632409; called by muse, mutect2, varscan2
- CRKL | c.434A>C p.K145T | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV62884596; called by muse, mutect2, varscan2
- CRTAC1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs779680902, COSV54010684; called by muse, mutect2, varscan2
- CRTAM | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 39/208 reads (19%) | catalogued as COSV57071707; called by muse, varscan2
- CRYBG1 | c.4509T>G p.I1503M | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV64814916; called by muse, mutect2, varscan2
- CRYBG3 | c.6187G>T p.D2063Y | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51710479, COSV51713455, COSV51716583; called by muse, mutect2, varscan2
- CRYGB | c.464T>C p.F155S | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV53681205; called by muse, mutect2, varscan2
- CRYL1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as rs760113420, COSV53421119; called by mutect2, varscan2
- CSDE1 | c.971G>A p.R324Q (on ENST00000358528 / NM_001007553.3; = p.R293Q on NM_007158.6) | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1004542230, COSV54762035; called by muse, mutect2, varscan2
- CSF2RA | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.117); catalogued as rs201854740, COSV100818008, COSV62623853; called by muse, mutect2
- CSMD1 | c.8422C>T p.R2808C (on ENST00000520002; = p.R2807C on NM_033225.6) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267601889, COSV59294672; called by muse, mutect2, varscan2
- CSMD1 | c.7855C>T p.R2619* (on ENST00000520002; = p.R2618* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as rs766376387, COSV59284438, COSV59393692; called by muse, mutect2, varscan2
- CSMD2 | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV53968842; called by muse, mutect2, varscan2
- CSMD3 | c.3578G>A p.R1193Q (on ENST00000297405 / NM_001363185.1; = p.R1089Q on NM_052900.3) | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1323845975, COSV52111209; called by muse, mutect2
- CSMD3 | c.3002A>C p.E1001A (on ENST00000297405 / NM_001363185.1; = p.E897A on NM_052900.3) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52334334; called by muse, varscan2
- CSPP1 | c.3773C>T p.S1258L (on ENST00000676605; = p.S1217L on NM_024790.6) | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768228167, COSV51593356; called by muse, mutect2, varscan2
- CST1 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV59056512; called by muse, mutect2, varscan2
- CSTF2T | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs199680831, COSV58657690; called by muse, mutect2, varscan2
- CT45A10 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1290230048, COSV65921075, COSV65921153; called by muse, mutect2, varscan2
- CTCFL | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 75/114 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs765675257, COSV54773669; called by muse, mutect2, varscan2
- CTHRC1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.122); catalogued as rs374084026; called by muse, mutect2
- CTHRC1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 93/344 reads (27%) | catalogued as COSV57716396; called by muse, mutect2, varscan2
- CTNNA1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as rs201498915, COSV57069365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV65623738; called by muse, mutect2, varscan2
- CTNNB1 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 23/130 reads (18%) | catalogued as COSV62718496; called by muse, mutect2, varscan2
- CTNS | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as rs555311279, COSV50439978; called by muse, mutect2, varscan2
- CTR9 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1391585643, COSV63728784; called by muse, mutect2, varscan2
- CTR9 | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV63729729; called by muse, mutect2, varscan2
- CTSC | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 54/284 reads (19%) | catalogued as COSV57060689; called by muse, mutect2
- CTSE | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV63062015; called by muse, mutect2, varscan2
- CTSL | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV58246656, COSV58247738; called by muse, mutect2, varscan2
- CTSV | c.789C>T p.G263= | Splice Region (SNP) | VAF 15/78 reads (19%) | catalogued as rs1448584052, COSV52345910; called by muse, mutect2, varscan2
- CUBN | c.7784G>T p.R2595I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV64718797; called by muse, mutect2
- CUBN | c.7075G>T p.D2359Y | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64728470; called by muse, mutect2, varscan2
- CUBN | c.4353C>A p.I1451= | Splice Region (SNP) | VAF 16/135 reads (12%) | catalogued as COSV64720024; called by muse, mutect2, varscan2
- CUL5 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV67610363; called by muse, mutect2, varscan2
- CUZD1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as rs142209822; called by muse, mutect2, varscan2
- CX3CR1 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1376191981; called by muse, mutect2, varscan2
- CYB5R4 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV63752487; called by muse, mutect2, varscan2
- CYBB | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781887034, COSV66084815; called by muse, mutect2, varscan2
- CYLC2 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66339383; called by muse, mutect2
- CYLC2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs753247753, COSV66336189; called by muse, mutect2, varscan2
- CYP24A1 | c.635T>G p.F212C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53776995; called by muse, mutect2, varscan2
- CYP27C1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.075); catalogued as COSV100080016, COSV58867378; called by muse, mutect2, varscan2
- CYP2R1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs61744571, COSV58126974; called by muse, mutect2, varscan2
- CYP3A4 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1309748501, COSV60504503; called by muse, mutect2, varscan2
- CYP3A43 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV104412771, COSV55937138; called by muse, mutect2
- CYP4B1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs773003953, COSV54722263; called by mutect2, varscan2
- CYP4F11 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV56126099; called by muse, mutect2, varscan2
- CYP4F2 | c.1123C>A p.L375M | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55622123; called by muse, mutect2, varscan2
- CYP7B1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.139); catalogued as COSV59598060; called by muse, mutect2, varscan2
- CYP8B1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779913482, COSV60227804; called by muse, mutect2, varscan2
- CYSLTR1 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV64819490; called by muse, mutect2, varscan2
- DAAM1 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs973543535, COSV100658717; called by muse, mutect2
- DACT1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 52/98 reads (53%) | catalogued as COSV60023808; called by muse, mutect2, varscan2
- DBF4B | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs146661795; called by mutect2, varscan2
- DCAF11 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 85/108 reads (79%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.227); catalogued as rs143599073; called by muse, mutect2, varscan2
- DCAF4L1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1224359974, COSV60787139; called by muse, mutect2, varscan2
- DCAF4L1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60788773; called by muse, mutect2, varscan2
4,342 further variants in this file (3,179 protein-altering or splice-affecting, 950 silent, 213 other) are not listed here.
